Gene-level copy-number profile of tumor specimen TCGA-VQ-A8P5-01A from TCGA case TCGA-VQ-A8P5, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 67.3 years (24,571 days).
Specimen TCGA-VQ-A8P5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.a624149e-2a88-4e2e-b7f9-cdc14f4964e5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8P5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3eaaf0c5-5e42-4d7e-8a3f-7a952ee6bbee

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 2,840; copy number 2: 22,859; copy number 3: 20,020; copy number 4: 9,577; copy number 5: 3,046; copy number 6: 521; copy number 7: 266; copy number 8: 272; copy number 9: 157; copy number 10: 43; copy number 11: 12; copy number 12: 8; copy number 13: 115; copy number 14: 16; copy number 45: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8P5-01A-11D-A396-01): tumor purity 0.49, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr9:2,228,961–3,053,408, 10 genes: RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,473 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,042,184–241,357,230, 55 genes, copy number 5 (within-gene range 4–5): RYR2, RN7SKP195, MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1.
- chr2:114,442,299–117,539,464, 17 genes, copy number 5 (within-gene range 4–5): DPP10, DPP10-AS3, DPP10-AS2, AC093610.1, DPP10-AS1, RPSAP23, AC016721.1, AC104408.1, AC062016.1, MTCYBP39, AC062016.2, MTND1P28, MTND2P21, MTCO1P43, RNU7-190P, AC092170.1, AC064856.1.
- chr3:108,958,248–110,727,121, 25 genes, copy number 5 (within-gene range 4–5): MORC1, U3, MORC1-AS1, C3orf85, AC063923.2, LINC00488, RNU6-1236P, AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15, MIR4445, AC078980.1, DIMT1P1, NFYBP1, AC078918.1, AC117430.1, RNU6ATAC15P, RPSAP29, Y_RNA.
- chr3:137,880,295–198,222,513, 1,058 genes, copy number 5–6 (broad region; genes not listed).
- chr6:146,824,539–148,157,084, 14 genes, copy number 5 (within-gene range 3–5): STXBP5-AS1, AL138916.1, AL138916.2, LUADT1, STXBP5, AL355365.1, YAP1P1, SAMD5, AL033504.1, AL365271.1, AL445123.2, AL445123.1, AL359382.1, AL359382.2.
- chr7:108,147,623–108,569,666, 3 genes, copy number 6 (within-gene range 3–6): NRCAM, PNPLA8, RPL7P32.
- chr8:50,490,795–50,491,465, 1 gene, copy number 7: AC090539.2.
- chr8:51,721,670–58,582,859, 117 genes, copy number 5–9 (broad region; genes not listed).
- chr8:58,588,420–58,588,764, 1 gene, copy number 5: AC068522.1.
- chr8:64,798,804–66,197,315, 19 genes, copy number 5: AC104232.3, AC104232.1, AC087808.1, RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967.
- chr8:72,537,225–74,321,540, 44 genes, copy number 5–8 (within-gene range 3–8): KCNB2, HAUS1P3, AC013562.2, AC013562.1, AC090735.1, AC022893.2, TERF1, RNU6-285P, AC022893.3, AC022893.1, SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1, STAU2, AC018620.1, AC100784.1, VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1.
- chr8:74,347,757–74,376,793, 2 genes, copy number 5: AC103952.1, Y_RNA.
- chr8:79,747,351–91,219,236, 178 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr8:97,624,203–108,443,496, 205 genes, copy number 6–13 (within-gene range 4–13) (broad region; genes not listed).
- chr8:109,086,585–116,403,757, 48 genes, copy number 6–7: TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1.
- chr8:118,620,498–124,247,398, 93 genes, copy number 6–12 (broad region; genes not listed).
- chr8:124,823,702–130,443,674, 83 genes, copy number 6–10 (within-gene range 4–10) (broad region; genes not listed).
- chr8:139,600,838–145,066,685, 208 genes, copy number 5–7 (broad region; genes not listed).
- chr10:27,775,186–27,999,079, 1 gene, copy number 5 (within-gene range 4–5): ARMC4.
- chr10:27,904,209–28,941,910, 25 genes, copy number 5: RPL36AP55, AL390866.1, MRPS21P5, MPP7, AL355501.1, MIR8086, MPP7-DT, ZNF101P1, U3, LINC02652, RPSAP10, RN7SKP39, WAC-AS1, WAC, RNU4ATAC6P, TPRKBP1, RNU6-1067P, BAMBI, LINC01517, AL355376.1, RNU6-270P, LINC00837, AL355376.2, RNA5SP308, RPL21P93.
- chr12:2,959,330–29,381,189, 666 genes, copy number 5–14 (broad region; genes not listed).
- chr12:33,923,374–34,058,745, 5 genes, copy number 9: RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2.
- chr13:23,328,826–30,996,138, 170 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr13:37,220,860–38,373,935, 12 genes, copy number 5: RPS12P24, LINC01048, LINC00547, POSTN, TRPC4, RNA5SP26, AL356495.1, LINC02334, HSPD1P9, LINC00571, UFM1, AL356863.1.
- chr16:15,701,237–17,470,960, 44 genes, copy number 5–11 (within-gene range 3–11): AC026401.3, MYH11, AF001548.2, AF001548.1, AF001548.3, CEP20, RNU6-213P, AC130651.1, RPL15P20, ABCC1, RPL17P40, ABCC6, AC136624.1, NOMO3, AC136624.3, AC136624.2, MIR3179-2, MIR3670-2, AC138969.2, MIR3180-2, PKD1P1, Y_RNA, AC138969.1, MIR6511A2, MIR6770-2, AC138969.3, PKD1P2, MIR6511A3, NPIPA7, AC136619.1, AC136431.1, AC136619.2, AC136431.2, AC092326.1, AC098965.1, AC109446.3, TCERG1P2, AC109446.1, XYLT1, AC109446.2, AC099494.1, AC099494.2, AC099494.3, AC009152.6.
- chr16:23,690,310–23,713,226, 1 gene, copy number 5 (within-gene range 4–5): ERN2.
- chr16:23,711,990–26,137,685, 43 genes, copy number 5 (within-gene range 4–5): AC012317.1, AC012317.2, CHP2, PRKCB, AC130454.1, AC130448.1, MIR1273H, AC130448.2, LINC02194, CACNG3, AC004125.1, RNU7-24P, AC008938.1, RBBP6, TNRC6A, LINC01567, AC008731.1, SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT, LINC02191, CYCSP39, HS3ST4, AC093516.1, AC093524.1, MIR548W, RNA5SP405, HMGN2P3, HSPE1P16.
- chr17:39,461,486–43,305,397, 263 genes, copy number 8–45 (broad region; genes not listed).
- chr19:42,977,463–58,605,223, 1,072 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,364. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
